Gene-level copy-number profile of tumor specimen TCGA-QR-A70V-01A from TCGA case TCGA-QR-A70V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 66.9 years (24,437 days).
Specimen TCGA-QR-A70V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.bfad9a33-c9da-4476-996f-e0fdbcd3a371.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A70V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS.
https://portal.gdc.cancer.gov/files/a054dcc9-c285-4daf-b9ce-3887afb7a51c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 8,916; copy number 2: 50,773; copy number 3: 110.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:114,576,041–114,579,970, 1 gene: LINC01957.
- chr5:125,966,777–125,968,085, 1 gene: RPSAP37.
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr8:131,712,512–131,712,980, 1 gene: AC060788.1.
- chr10:38,783,004–42,281,819, 6 genes: AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr10:88,759,982–88,779,626, 1 gene: LIPN.
- chr11:81,552,226–81,556,425, 2 genes: MTND4LP18, MTND6P25.
- chr11:87,879,473–87,880,095, 1 gene: AP000676.4.
- chr19:27,638,483–27,794,005, 3 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,915. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
